FM case AD16000 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Adrenal gland.
https://portal.gdc.cancer.gov/cases/61e0bf72-dae9-4b7f-bcb0-84f0ff0c578a

Female, 23.3 years: Adrenal cortical carcinoma (ICD-O-3 8370/3) of the adrenal gland. Tumor nuclei on the sequenced sample's slide: 52% (pathologist estimate recorded by GDC). Sample type: Tumor.
